Somatic mutation profile of tumor specimen C3L-05888-54 (aliquot CPT0344130001) from CPTAC case C3L-05888, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 71.5 years (26,116 days).
Specimen C3L-05888-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7a79aee-7c28-4459-85e8-7b1c1b5aac33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05888-50 (Buccal Cell Normal), aliquot CPT0344100003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d8b311a-1221-413e-a022-99e13374dafe

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Del 1, Silent 1, Intron 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 207/494 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DENND2C | c.2525G>A p.R842H (on ENST00000393274 / NM_001256404.2; = p.R785H on NM_198459.4) | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs769473985, COSV67922139; called by muse, mutect2, varscan2
- DIP2B | c.1855A>G p.M619V | Missense Mutation (SNP) | VAF 173/412 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs768405640, COSV56581352; called by muse, mutect2, varscan2
- NPAS4 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV60649253; called by muse, mutect2, varscan2
- RUNX1 | c.391T>G p.F131V (on ENST00000344691 / NM_001001890.3; = p.F158V on NM_001754.5) | Missense Mutation (SNP) | VAF 336/730 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55872756, COSV55884417, COSV55891302; called by muse, mutect2, varscan2
- SERPINB13 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.452); catalogued as rs1449207426; called by muse, varscan2
- TET2 | c.3860T>C p.F1287S | Missense Mutation (SNP) | VAF 130/344 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV54400116, COSV54437711; called by muse, mutect2, varscan2
- ZNF628 | c.1462G>A p.G488S | Missense Mutation (SNP) | VAF 190/393 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1244853787, COSV99219964; called by muse, mutect2, varscan2
- CCN5 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 199/461 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMBT1 | c.5216C>A p.A1739D (on ENST00000338354 / NM_001377530.1; = p.A982D on NM_004406.3) | Missense Mutation (SNP) | VAF 205/480 reads (43%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- KLC4 | c.1282G>C p.A428P | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMAD6 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 282/555 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TET2 | c.4044+1del | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | called by mutect2, pindel, varscan2
- USP9X | c.3178_3181dup p.C1061Yfs*14 | Frame Shift Ins (INS) | VAF 46/56 reads (82%) | called by pindel, varscan2
- ZNF730 | c.917A>T p.H306L | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM71C | c.24G>A p.P8= | Silent (SNP) | VAF 76/146 reads (52%) | catalogued as rs562310463, COSV60942533; called by mutect2, varscan2
- ANKRD11 | c.-422C>T | 5'UTR (SNP) | VAF 108/257 reads (42%) | called by muse, mutect2, varscan2
- TJP1 | c.1010+903C>T | Intron (SNP) | VAF 104/255 reads (41%) | called by muse, mutect2, varscan2
